HCMI case HCM-BROD-0650-C56 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/05cbd57f-0c12-486e-8ced-edb9ed3cbbb0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1949; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Classification of tumor: primary; Age at diagnosis: 67.2 years (24,542 days); Tumor grade: High Grade; Prior malignancy: yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 7 days; Days to treatment end: 85 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 542 days (1.5 years); Days to treatment end: 964 days (2.6 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 670 days (1.8 years); Days to treatment end: 964 days (2.6 years).
   Recorded as not given: adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/6; ICD-10 code: C78.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Peritoneum, NOS; Classification of tumor: metastasis; Age at diagnosis: 69.2 years (25,274 days); Days to diagnosis: 732 days (2.0 years); Peritoneal fluid cytological status: Malignant; Sites of involvement: Ovary, NOS / Abdominal Peritoneum.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Maintenance Therapy; Days to treatment start: 7 days; Days to treatment end: 85 days; Treatment outcome: Progressive Disease.

Follow-up (1 entry)
- Days to follow up: 964 days (2.6 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- BRCA1 mutation, nos (Targeted Sequencing): Negative.
- BRCA2 mutation, nos (Targeted Sequencing): Negative.
- CA-125: 606.
- HNF1A (IHC): Negative.
- MLH1 (IHC): Negative.
- MLH1 hypermethylation: Negative.
- MSH6 (IHC): Negative.
- PMS2 (IHC): Negative.
- WT1 (IHC): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 20.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples)
- Sample HCM-BROD-0650-C56-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
- Sample HCM-BROD-0650-C56-12A: Sample type: Saliva; Tissue type: Normal; Specimen type: Saliva; Preservation method: Frozen.
- Sample HCM-BROD-0650-C56-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
